Gene-level copy-number profile of tumor specimen TCGA-P3-A6T6-01A from TCGA case TCGA-P3-A6T6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower gum; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 53.9 years (19,694 days).
Specimen TCGA-P3-A6T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.210753af-4d66-480d-9e35-dcb1eb2b3063.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A6T6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddb97573-b4d9-40a6-95c2-9ab0c535f970

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,485; copy number 2: 47,137; copy number 3: 4,580; copy number 4: 146; copy number 5: 352; copy number 6: 106; copy number 8: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A6T6-01A-11D-A34I-01): tumor purity 0.72, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 472 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:129,415,949–145,066,685, 312 genes, copy number 5 (broad region; genes not listed).
- chr17:14,705,076–14,780,686, 3 genes, copy number 8: RPS18P12, AC013248.1, AC005863.1.
- chr17:15,365,323–17,347,663, 106 genes, copy number 6 (broad region; genes not listed).
- chr17:50,862,223–50,944,713, 4 genes, copy number 8 (within-gene range 2–8): TOB1, TOB1-AS1, AC005920.4, AC005920.1.
- chr18:71,890,409–75,508,114, 47 genes, copy number 5–8: AC069114.1, AC069114.2, CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922, DIPK1C, AC009704.3, CNDP2, AC009704.2, CNDP1, AC009704.1, LINC00909, ZNF407, AC015819.2, AC015819.1, AC015819.4, AC015819.3, AC015819.5, ZADH2, TSHZ1, AC116003.3, AC116003.1, SMIM21, AC116003.2, AC012101.2, AC012101.1, AC090812.1.

Autosomal genes at a single copy (total copy number 1): 6,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
